Gene-level copy-number profile of tumor specimen ALCH-B1YL-TTP1-A from ALCHEMIST case ALCH-B1YL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 59.7 years (21,812 days).
Specimen ALCH-B1YL-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e593ead2-8639-43c0-bbb0-a50dc2cd4f30.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1YL-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/dbfb197a-5115-4153-b807-d01c68417cef

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 297; copy number 1: 2,825; copy number 2: 55,360; copy number 3: 395; copy number 4: 18; copy number 5: 14; copy number 8: 1; copy number 13: 2.

Homozygous deletions (total copy number 0; autosomes only): 31 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:228,100,726–228,182,257, 9 genes: C1orf35, MRPL55, FAM96AP2, AL359510.2, AL359510.1, GUK1, GJC2, IBA57-DT, IBA57.
- chr5:134,874,371–134,901,635, 1 gene: TXNDC15.
- chr7:102,650,325–102,661,398, 1 gene (within-gene range 0–3): SPDYE2B.
- chr11:1,469,457–1,501,247, 1 gene: MOB2.
- chr16:668,105–768,865, 17 genes (within-gene range 0–2): RHOT2, RHBDL1, LINC02867, Z92544.2, STUB1, JMJD8, WDR24, Z92544.1, FBXL16, Z97653.2, Z97653.1, METRN, ANTKMT, CCDC78, HAGHL, CIAO3, MSLN.
- chr16:32,034,853–32,035,326, 1 gene (within-gene range 0–1): IGHV1OR16-1.
- chr16:32,066,065–32,066,358, 1 gene (within-gene range 0–1): IGHV3OR16-9.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 16 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:102,479,976–102,517,777, 1 gene, copy number 5 (within-gene range 4–7): RASA4B.
- chr7:102,681,836–102,690,469, 1 gene, copy number 8: RASA4DP.
- chr11:32,892,811–33,237,409, 12 genes, copy number 5: QSER1, Y_RNA, DEPDC7, TCP11L1, PIGCP1, LINC00294, CSTF3, CSTF3-DT, Y_RNA, RPL29P23, Y_RNA, AL136126.1.
- chr21:43,461,960–43,479,534, 2 genes, copy number 13 (within-gene range 13–19): LINC00313, AP001048.1.

Autosomal genes at a single copy (total copy number 1): 294. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
